Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3428, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3428-01A (Primary Tumor).

[page 1 of 2]
Clinical History/Diagnosis: Left renal mass.

Source of Specimen(s):

A: Left kidney, adrenal and para aortic lymph nodes

B: Additional para aortic tissue

Gross Description:

Received in two parts.

Source of Tissue: 1. Labeled #1 "left kidney, adrenal, para-aortic lymph nodes"

Frozen Section Diagnosis: IFS CLEAR CELL CARCINOMA AS

Gross Description: Received fresh for frozen section diagnosis is a kidney with attached perinephric fat weighing 1988.28 gm and measuring 24 x 14.5 x 11.5 cm. Examination of the hilum reveals the vascular resection margins. Grossly, the ureter appears to insert in the region of the lower pole. The venous resection margin appears to be free of tumor; however, upon opening the vein, adherent tumor thrombus is identified. No tumor is present at the resection margin itself. Bivalving the kidney reveals a large, yellow-orange and hemorrhagic tumor occupying the majority of the kidney. There is some recognizable renal parenchyma identified in the lower pole of the kidney. The tumor measures approximately 12 x 9.5 x 9 cm. A representative section of the tumor is submitted for frozen section analysis. The frozen residue will be submitted for permanent analysis. A section of the tumor is submitted for cytogenetic analysis. Sectioning through the remainder of the specimen reveals tumor invading into perinephric fat, grossly 2 mm from the inked margin. An adrenal gland is identified measuring approximately 9 x 2 x 0.5 cm. There is a nodule within the adrenal measuring 0.7 x 0.5 x 0.3 cm. The specimen is dissected for lymph nodes and possible lymph nodes are submitted. Representative sections of the specimen are submitted.

Designation of Sections: IFS frozen section, 1A vascular and ureteral resection margins, 1B tumor thrombus within vein, 1C tumor extending into perinephric fat (with inked margin), 1D tumor section with possible vascular invasion, 1E tumor section with kidney and perinephric fat, 1F section of tumor, 1G-1K possible lymph nodes, 1L section of adrenal including nodule

Summary of Sections: 13 IFS through 1L - multiple

Source of Tissue: 2. Labeled #2 "additional para-aortic tissue"

Gross Description: Received fresh is a portion of fibrofatty tissue measuring 2 x 1 x 0.5 cm. No gross lymph node is identified. The entire

[page 2 of 2]
specimen is submitted.

Designation of Sections: 2A

Summary of Sections: 1 2A,2

Final Diagnosis:

1. Kidney, left, adrenal, and para-aortic lymph nodes (radical nephrectomy):

- Renal cell carcinoma, clear cell type (12 cm); Fuhrman nuclear grade 2, invading through the renal capsule into the perinephric fat.
- Tumor thrombus is present within the renal vein.
- Carcinoma is approximately 2.5 mm from the inked perinephric fat margin.
- Negative vascular and ureteral margins.
- Four negative lymph nodes (0/4).
- Adrenal gland with benign lipomatous inclusion.

2. Additional para-aortic tissue (excision):

- Fibroadipose tissue, no lymphoid tissue seen, no tumor seen.

Source: NCI Genomic Data Commons file 8d96e2b2-b5a6-42a3-a8e2-92f8ca95b46d (TCGA-AK-3428.1454EC74-1C64-44A6-BF9F-DCA88073F6A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).